Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5L3, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5L3-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Tumor, Adrenal Cortical of unknown/
uncertain behavior 8370 KB

Site: Adrenal Gland, cortex @ 74.0

QW 2/6/13

Reference Pathology only:

Diagnosis: adrenocortical carcinoma

Process - if case passes we can request
more path - may not ship if not
malignant.

[page 2 of 2]
Patient # from Tissue Source Site

Date of report

Date of Surgery/specimen collection

Site (confirmed to be adrenal) with laterality indicated

Tumor size(s)

Histologic diagnosis

ACC

Lymph Node Status

X

Pathologic information

Weiss score

Source: NCI Genomic Data Commons file 48608cfa-8594-40c1-925f-aee0cea8a7a9 (TCGA-OR-A5L3.FE1CF238-753C-4DF4-A083-74DDC753DF45.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).